Gene-level copy-number profile of tumor specimen HCM-BROD-0615-C16-06A from HCMI case HCM-BROD-0615-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 72.7 years (26,543 days).
Specimen HCM-BROD-0615-C16-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file db18f98b-cc6a-4a9e-81c9-1cb60b0a1554.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0615-C16-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,239 have no estimate.
https://portal.gdc.cancer.gov/files/093b3905-5b48-470a-b65f-0482660642d3

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 28; copy number 2: 3,270; copy number 3: 18,806; copy number 4: 16,177; copy number 5: 9,955; copy number 6: 6,390; copy number 7: 1,683; copy number 8: 825; copy number 9: 186; copy number 10: 278; copy number 11: 196; copy number 12: 24; copy number 13: 42; copy number 14: 3; copy number 15: 14; copy number 16: 80; copy number 17: 7; copy number 18: 39; copy number 20: 2; copy number 21: 41; copy number 24: 184; copy number 27: 71; copy number 33: 1; copy number 36: 15; copy number 38: 21; copy number 49: 4; copy number 52: 2; copy number 80: 39.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:79,703,227–79,714,681, 1 gene (within-gene range 0–3): NUTM2B.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,757 genes in 56 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–36,081, 6 genes, copy number 11: DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A.
- chr1:12,527,724–12,693,020, 7 genes, copy number 11: LINC02766, DHRS3, RNU6ATAC18P, MIR6730, AC254633.1, AADACL4, AC244670.1.
- chr2:38,814–40,679,604, 659 genes, copy number 7–9 (broad region; genes not listed).
- chr2:41,143,780–51,225,575, 163 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr2:89,297,264–91,580,863, 47 genes, copy number 8–11: IGKV1-37, IGKV2-38, IGKV1-39, IGKV2-40, 5S_rRNA, IGKV2D-40, IGKV1D-39, IGKV2D-38, IGKV1D-37, IGKV2D-36, IGKV1D-35, IGKV3D-34, IGKV1D-33, IGKV1D-32, IGKV3D-31, IGKV2D-30, IGKV2D-29, IGKV2D-28, IGKV1D-27, IGKV2D-26, IGKV3D-25, IGKV2D-24, IGKV2D-23, IGKV1D-22, IGKV6D-21, IGKV3D-20, IGKV2D-19, IGKV2D-18, IGKV6D-41, IGKV1D-17, IGKV1D-16, IGKV3D-15, IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11, IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7, AC233263.2, IGKV1OR2-118, AC233263.1, AC233263.7, AC233266.1, AC233266.2.
- chr2:134,735,464–135,531,218, 10 genes, copy number 8 (within-gene range 5–8): CCNT2-AS1, VDAC2P4, AC110620.1, ACMSD, MIR5590, CCNT2, MAP3K19, RAB3GAP1, SNORA40B, ZRANB3.
- chr3:152,118,173–152,465,780, 4 genes, copy number 7 (within-gene range 6–7): AC108718.1, MBNL1, MBNL1-AS1, TMEM14EP.
- chr3:160,227,454–161,821,908, 28 genes, copy number 7 (within-gene range 6–7): AC079594.1, IFT80, RPL35AP10, SMC4, MIR15B, MIR16-2, TRIM59, B3GAT3P1, RNU7-136P, KPNA4, SCARNA7, KRT8P12, RPL6P8, ARL14, SNORA72, AC069224.1, PPM1L, B3GALNT1, NMD3, AC108738.1, EEF1GP4, PSMC1P7, SPTSSB, LINC02067, AC112491.1, RPL23AP42, OTOL1, AC131211.1.
- chr4:38,758,791–43,410,937, 98 genes, copy number 8–17 (broad region; genes not listed).
- chr4:43,763,134–44,025,516, 5 genes, copy number 7–10: AC080132.1, RN7SL193P, NDUFB4P12, AC114757.1, LINC02475.
- chr5:83,426,676–84,384,880, 11 genes, copy number 7 (within-gene range 4–7): FTH1P9, VCAN, VCAN-AS1, HAPLN1, RN7SKP295, RNU6-620P, AC020899.1, RNU4-11P, ZP3P1, EDIL3, RNU6-448P.
- chr6:10,747,759–12,008,856, 30 genes, copy number 8–13 (within-gene range 3–13): TMEM14B, AL024498.2, RNA5SP203, MAK, GCM2, AL357497.1, SYCP2L, ELOVL2, AL121955.1, ELOVL2-AS1, SMIM13, ERVFRD-1, AL136139.1, AL139807.1, NEDD9, AL022098.1, AL445430.2, AL445430.1, RNU1-64P, THAP12P5, TMEM170B, AL357518.1, Metazoa_SRP, AL022724.1, ADTRP, AL022724.3, AL022724.2, AMD1P4, AL157373.1, AL157373.2.
- chr6:13,357,830–15,113,221, 26 genes, copy number 10–14: GFOD1, GFOD1-AS1, RPS4XP7, RN7SKP204, SIRT5, AL441883.1, NOL7, RANBP9, Z93020.1, MCUR1, AL023583.1, RNF182, MRPL35P1, AL022396.1, CD83, AL133259.1, RNU7-133P, AL353152.1, LINC01108, AL080313.2, AL080313.1, AL109914.1, RNU6-793P, AL138720.1, AL050335.1, RN7SL332P.
- chr6:24,171,755–25,057,073, 26 genes, copy number 7–9 (within-gene range 7–13): DCDC2, KAAG1, RNU6-391P, MRS2, GPLD1, ALDH5A1, KIAA0319, KRT8P43, TDP2, ACOT13, AL031775.1, C6orf62, AL031775.2, LINC02828, AL133264.1, GMNN, ARMH2, AL512428.1, RIPOR2, MTCO2P33, PPIAP29, AL160400.1, ASS1P1, RN7SL334P, AL133268.3, AL133268.2.
- chr6:25,782,915–26,219,240, 41 genes, copy number 9: SLC17A1, SLC17A3, H2AC3P, H2BP5, SLC17A2, TRIM38, U91328.2, U91328.1, U91328.3, H3P26, H1-1, H3C1, H4C1, H4C2, H3C2, H2AC4, H2BC3, H2AC5P, H3C3, H1-2, HFE, H4C3, H1-6, H2BC4, H2AC6, H1-4, H2BC5, AL353759.1, LARP1P1, H2BC6, H4C4, H1-12P, AL031777.2, H3C4, H2AC7, H2BC7, AL031777.1, H4C5, H2BC8, H2AC8, H3C5P.
- chr6:26,871,484–27,524,339, 31 genes, copy number 18: GUSBP2, POM121L6P, LINC00240, AL133255.1, AL590062.1, VN1R12P, VN1R13P, VN1R11P, RNU2-62P, AL021807.1, H2BC11, H2AC11, H4C9, H2BC12, H2AC12, MIR3143, RPL10P2, PRSS16, AL021808.1, POM121L2, VN1R10P, ZNF204P, ZNF391, AL031118.1, MCFD2P1, ZNF184, AL021918.4, AL021918.3, AL021918.2, AL021918.1, HNRNPA1P1.
- chr6:27,596,412–27,824,480, 12 genes, copy number 7–12: RNU6-471P, RPL8P1, LINC01012, GPR89P, RSL24D1P1, H4C10P, H2BC13, H2AC13, H3C10, H2AC14, H2BC14, H4C11.
- chr6:28,281,572–30,326,134, 132 genes, copy number 11–16 (within-gene range 4–16) (broad region; genes not listed).
- chr6:30,259,584–32,041,644, 175 genes, copy number 7–16 (within-gene range 3–16) (broad region; genes not listed).
- chr6:40,713,411–43,053,945, 80 genes, copy number 10–21 (within-gene range 3–21) (broad region; genes not listed).
- chr6:43,576,185–44,265,788, 26 genes, copy number 10–15: POLH, POLH-AS1, GTPBP2, MAD2L1BP, RSPH9, MRPS18A, AL136131.1, AL136131.2, VEGFA, AL136131.3, LINC02537, AL157371.1, AL109615.3, C6orf223, AL109615.2, AL109615.1, MRPL14, TMEM63B, CAPN11, RN7SL811P, MYMX, SLC29A1, HSP90AB1, SLC35B2, MIR4647, NFKBIE.
- chr6:47,368,943–47,627,263, 5 genes, copy number 18: B3GNTL1P2, AL355353.1, CD2AP, Y_RNA, AL358178.1.
- chr6:49,344,800–49,528,078, 5 genes, copy number 17–18: RNU7-65P, EEF1A1P42, MMUT, CENPQ, GLYATL3.
- chr7:484,107–2,614,733, 58 genes, copy number 7: AC147651.1, PDGFA, HRAT92, PRKAR1B, PRKAR1B-AS2, PRKAR1B-AS1, DNAAF5, SUN1, GET4, AC073957.3, ADAP1, COX19, CYP2W1, C7orf50, MIR339, AC073957.1, GPR146, AC073957.2, AC091729.1, AC091729.2, GPER1, ZFAND2A, ZFAND2A-DT, UNCX, AC073094.1, MICALL2, AC102953.1, AC102953.2, INTS1, AC093734.1, MAFK, TMEM184A, PSMG3, PSMG3-AS1, TFAMP1, AC074389.2, ELFN1, AC074389.3, AC074389.1, ELFN1-AS1, MAD1L1, AC069288.1, AC104129.1, MIR4655, MRM2, NUDT1, SNX8, MIR6836, IMMP1LP3, EIF3B, AC004840.1, AC004840.2, CHST12, GRIFIN, LFNG, MIR4648, BRAT1, IQCE.
- chr7:5,274,369–39,949,755, 589 genes, copy number 7–8 (broad region; genes not listed).
- chr7:43,582,758–45,088,969, 58 genes, copy number 7: STK17A, COA1, BLVRA, AC005189.1, MRPS24, URGCP-MRPS24, URGCP, TUBG1P, UBE2D4, POLR2J4, AC004951.4, AC004951.3, AC004951.2, SPDYE1, AC004951.1, AC017116.2, POLR2J4, RASA4CP, LINC00957, DBNL, MIR6837, PGAM2, AC017116.1, POLM, MIR6838, AEBP1, MIR4649, POLD2, RNA5SP230, MYL7, GCK, YKT6, CAMK2B, AC004453.2, NUDCD3, AC004453.1, RNU6-1097P, AC004938.1, NPC1L1, DDX56, TMED4, AC011894.1, OGDH, ZMIZ2, AC013436.1, PPIA, H2AZ2, LINC01952, PURB, MIR4657, AC004854.2, AC004854.1, AC004847.1, MYO1G, SNHG15, SNORA9, CCM2, NACAD.
- chr7:47,987,148–51,729,716, 41 genes, copy number 7: SUN3, C7orf57, UPP1, ABCA13, AC091770.1, AC004899.1, AC004899.2, GDI2P1, CDC14C, AC091730.1, DDX43P2, AC093775.1, VWC2, ZPBP, GNL2P1, AC034148.1, SPATA48, AC020743.1, AC020743.2, AC020743.3, IKZF1, AC124014.1, RNU6-1091P, FIGNL1, DDC, DDC-AS1, GRB10, AC005153.1, AC004920.1, AC009296.1, AC004830.2, AC004830.1, COBL, RPL7L1P2, CICP17, AC012441.2, AC012441.1, AC005999.2, ROBO2P1, AC005999.1, RN7SL292P.
- chr7:92,560,758–103,989,658, 321 genes, copy number 20–52 (broad region; genes not listed).
- chr7:115,030,564–117,230,176, 43 genes, copy number 49–80 (within-gene range 3–80): LINC01393, LINC01392, RAC1P6, Y_RNA, POLR2DP2, SNORA25B, AC092590.1, AC093714.1, AC093714.2, Y_RNA, TFEC, AC073130.3, TES, AC073130.2, AC002066.1, AC073130.1, CAV2, Metazoa_SRP, CAV1, AC006159.1, AC006159.2, COMETT, MET, CAPZA2, AC002543.1, Y_RNA, RNA5SP239, ST7-AS1, AC106873.5, AC106873.7, ST7, ST7-OT4, AC106873.8, AC106873.3, AC106873.2, AC106873.6, AC106873.4, AC106873.1, TPM3P1, MIR6132, ST7-AS2, AC002542.6, AC002542.2.
- chr7:118,880,103–122,234,903, 31 genes, copy number 9–11: GTF3AP6, AC092098.1, AC079791.1, LINC02476, RNU1-29P, AC004946.1, AC004946.2, KCND2, RNU6-581P, AC004888.1, TSPAN12, ING3, RNA5SP240, CPED1, HMGN1P18, RNA5SP241, RNU6-517P, WNT16, FAM3C, CYCSP19, AC074085.1, AC074085.2, AC004875.1, RN7SKP277, PNPT1P2, PTPRZ1, AASS, RNU7-154P, AC015983.2, AC006020.1, AC015983.1.
- chr8:104,489,231–129,844,504, 277 genes, copy number 7–11 (within-gene range 6–11) (broad region; genes not listed).
- chr8:140,505,813–145,066,685, 197 genes, copy number 7–8 (broad region; genes not listed).
- chr10:120,069,980–122,699,846, 38 genes, copy number 7–8: AL355298.1, RPL21P16, AC073587.1, PLPP4, LINC01561, AC023282.1, WDR11-AS1, AL391425.1, WDR11, AC010998.2, AC010998.1, AC010998.3, RPL19P16, LINC01153, RN7SKP167, FGFR2, AC009988.1, RPS15AP5, AC025947.1, ATE1, Y_RNA, ATE1-AS1, AL731566.1, AL731566.3, NSMCE4A, AL731566.2, TACC2, AC063960.1, AC063960.2, BTBD16, RNU6-728P, PLEKHA1, MIR3941, BX842242.1, ARMS2, HTRA1, DMBT1, C10orf120.
- chr12:57,674,665–58,395,138, 33 genes, copy number 7: RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1.
- chr12:70,638,073–71,927,248, 21 genes, copy number 7: PTPRR, FAHD2P1, Y_RNA, AC123905.1, AC025575.1, AC025575.2, TSPAN8, LGR5, AC090116.1, AC078860.3, ZFC3H1, AC078860.1, THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1, AC089984.2, TBC1D15, MRS2P2.
- chr12:118,013,588–118,062,430, 4 genes, copy number 7: RFC5, AC131159.2, WSB2, AC131159.1.
- chr12:120,914,400–121,430,623, 18 genes, copy number 8 (within-gene range 6–8): CLIC1P1, RPL12P33, HNF1A-AS1, HNF1A, C12orf43, OASL, AC079602.2, AC079602.3, SNORA70, AC079602.1, P2RX7, AC069209.2, AC069209.1, P2RX4, CAMKK2, ANAPC5, AC048337.1, RNF34.
- chr13:29,864,372–30,660,770, 24 genes, copy number 8: Metazoa_SRP, TIMM8BP1, LINC00297, LINC00572, LINC00544, AL354674.1, LINC00365, LINC00384, LINC00385, AL157770.1, KATNAL1, RNU6-64P, PRDX2P1, LINC00427, LINC00426, AL356750.1, LINC01058, UBE2L5, HMGB1, AL353648.1, RBM22P2, MFAP1P1, PTPN2P2, USPL1.
- chr16:46,469,341–46,931,289, 18 genes, copy number 7: ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6, MYLK3, AC007225.1, C16orf87, CKBP1, AC007225.2, GPT2.
- chr20:30,214,765–43,189,970, 325 genes, copy number 7 (within-gene range 4–8) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 28. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
